Gene-level copy-number profile of tumor specimen TCGA-ED-A97K-01A from TCGA case TCGA-ED-A97K, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Combined hepatocellular carcinoma and cholangiocarcinoma; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 55.0 years (20,073 days).
Specimen TCGA-ED-A97K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.b0f0dd1e-192c-4e34-8806-833cad808f41.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ED-A97K-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0cfdd31c-5ecc-4463-b8f1-356f36175890

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 2,220; copy number 2: 16,116; copy number 3: 9,774; copy number 4: 29,748; copy number 5: 286; copy number 6: 739; copy number 7: 155; copy number 8: 17; copy number 9: 652; copy number 10: 8; copy number 12: 7; copy number 14: 13; copy number 16: 10; copy number 23: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ED-A97K-01A-21D-A381-01): tumor purity 0.38, ploidy 3.43, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 39 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,994,139–26,805,862, 36 genes: CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1.
- chr9:75,088,514–75,198,177, 3 genes (within-gene range 0–3): OSTF1, Y_RNA, RNU6-1228P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 720 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:50,398,825–64,181,498, 288 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr1:79,967,733–80,051,404, 1 gene, copy number 10 (within-gene range 2–10): AC099671.1.
- chr1:113,696,831–114,262,278, 16 genes, copy number 9: PHTF1, AL133517.1, RSBN1, AL137856.1, PTPN22, AP4B1-AS1, BCL2L15, AP4B1, DCLRE1B, HIPK1-AS1, HIPK1, OLFML3, AL591742.1, AL591742.2, SYT6, AL121999.1.
- chr2:38,814–4,945,383, 75 genes, copy number 9 (broad region; genes not listed).
- chr2:5,549,780–11,827,409, 131 genes, copy number 9 (broad region; genes not listed).
- chr2:11,836,933–11,836,986, 1 gene, copy number 9: MIR4262.
- chr2:15,166,914–19,348,067, 51 genes, copy number 9 (within-gene range 4–9): NBAS, RPS26P18, AC008278.2, DDX1, AC008278.1, LINC01804, AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.5, AC010745.4, AC010880.1, AC104623.1, AC104623.2, CYRIA, AC008164.1, AC008069.1, LINC01866, RN7SKP168, ZFYVE9P2, PSMC1P10, RAD51AP2, VSNL1, SMC6, GEN1, MSGN1, KCNS3, AC079802.1, AC079148.3, AC079148.2, AC079148.1, RDH14, NT5C1B-RDH14, NT5C1B, RNU6-1215P, AC106053.1, AC130814.1, LINC01376.
- chr12:30,926,428–34,249,958, 90 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr12:58,872,149–60,419,293, 20 genes, copy number 12–14: LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2.
- chr12:67,929,235–68,234,686, 7 genes, copy number 10 (within-gene range 1–10): LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG.
- chr12:68,746,125–70,443,923, 40 genes, copy number 16–23: SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P.

Autosomal genes at a single copy (total copy number 1): 124. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
